TCGA case TCGA-06-0221 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/054f472f-98cb-4559-b2e2-b5f800fc8eef

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 31 years; Vital status: Dead; Days to death: 603 days (1.7 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 31.0 years (11,333 days); Year of diagnosis: 2000; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Clinical Trial; Treatment intent type: Adjuvant; Days to treatment start: 14 days; Days to treatment end: 259 days; Number of cycles: 8; Treatment dose: 250 mg/day; Prescribed dose: 250; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 65 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Initial disease status: Progressive Disease; Days to treatment start: 280 days; Days to treatment end: 280 days; Number of cycles: 1; Treatment dose: 6 Wafer; Prescribed dose: 6; Prescribed dose units: Wafer; Route of administration: Intratumoral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: O6-Benzylguanine; Initial disease status: Progressive Disease; Days to treatment start: 280 days; Days to treatment end: 285 days; Number of cycles: 1; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 318 days; Days to treatment end: 471 days (1.3 years); Number of cycles: 6; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Isotretinoin; Initial disease status: Progressive Disease; Days to treatment start: 379 days (1.0 years); Days to treatment end: 471 days (1.3 years); Number of cycles: 4; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vatalanib; Initial disease status: Progressive Disease; Days to treatment start: 471 days (1.3 years); Days to treatment end: 502 days (1.4 years); Number of cycles: 1.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine + O6-Benzylguanine; Initial disease status: Progressive Disease; Days to treatment start: 502 days (1.4 years); Days to treatment end: 532 days (1.5 years); Number of cycles: 1.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 31.7 years (11,593 days); Days to diagnosis: 260 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 280 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (5 entries)
- Day 260 (post initial treatment): Progression or recurrence: Yes; Days to progression: 260 days.
- Days to follow up: 548 days (1.5 years); Disease response: With Tumor.
- Days to follow up: 603 days (1.7 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 100; Timepoint: Preoperative.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0221-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-06-0221-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 80; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-06-0221-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0.
- Sample TCGA-06-0221-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-0221-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-06-0221-02A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 85; Percent normal cells: 35; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-06-0221-02A-01-BS1: Section location: Bottom; Percent tumor cells: 20; Percent tumor nuclei: 20; Percent normal cells: 80; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-06-0221-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Gliadel Wafer.
- Drug treatment 1, Route of administrations: Route of administration: Intum.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Pharmaceutical therapy drug name: Carmustine (BCNU).
- Drug treatment 4: Pharmaceutical therapy drug name: Reinoid/CIS retinoic acid.
- Drug treatment 5: Pharmaceutical therapy drug name: 06-BG.
- Drug treatment 6: Pharmaceutical therapy drug name: CAI (NABTT 97212).
- Drug treatment 7: Pharmaceutical therapy drug name: 06-BG (NABTT 0803).
- Drug treatment 7, Route of administrations: Route of administration: IV.
- Drug treatment 8: Pharmaceutical therapy drug name: Vatalanib (PTK787).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 603 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 603 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 260 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0221-01A-01D-0236-01): tumor purity 0.83, ploidy 2.02, whole-genome doublings 0.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0221-02A-11D-2002-01): tumor purity 0.82, ploidy 1.96, whole-genome doublings 0.
